Somatic mutation profile of tumor specimen 0DJVPO from CCDI case PBBXKJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Spinal cord; Age at diagnosis: 2.8 years (1,019 days).
Specimen 0DJVPO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f7603ef-0d13-4679-9f7b-ec7753b931d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVPD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8728637-7562-4507-a682-724c26ac8cc3

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGB7 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 238/1161 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs766953169, COSV99914229; called by muse, varscan2
- PCNX3 | c.5104C>T p.R1702C | Missense Mutation (SNP) | VAF 418/978 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1023840698, COSV63139381; called by muse, varscan2
- USH2A | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 532/1366 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234360, COSV56347017, COSV56379080; called by muse, varscan2
- MEGF10 | c.1215C>T p.Y405= | Silent (SNP) | VAF 330/847 reads (39%) | catalogued as rs781762135, COSV99174685; ClinVar: uncertain significance; called by muse, varscan2
